Somatic mutation profile of tumor specimen TCGA-ER-A19O-06A (aliquot TCGA-ER-A19O-06A-11D-A197-08) from TCGA case TCGA-ER-A19O, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 56.9 years (20,788 days).
Specimen TCGA-ER-A19O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6263a081-0c9d-4be0-8650-856d77e6852b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ER-A19O-10A (Blood Derived Normal), aliquot TCGA-ER-A19O-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac0f3bd9-7c40-4b29-a8e0-4bae752e1d8d

The open-access MAF lists 213 somatic variants for this specimen: 141 protein-altering or splice-affecting, 66 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 66, Nonsense Mutation 7, RNA 3, Splice Region 3, 3'UTR 2, Splice Site 2, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- ETV6 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV67149820; called by muse, mutect2, varscan2
- ACTL6B | c.695dup p.N233Kfs*17 | Frame Shift Ins (INS) | VAF 25/120 reads (21%) | catalogued as rs779550102; called by mutect2, varscan2
- ADAMTS18 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51409142, COSV51409249; called by muse, mutect2, varscan2
- ALOX12 | c.1693C>A p.P565T | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52349658; called by muse, mutect2, varscan2
- ANKRD30A | c.383C>T p.S128F (on ENST00000611781; = p.S72F on NM_052997.2) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as rs746602413, COSV64609962, COSV64619095; called by muse, mutect2, varscan2
- ANXA10 | c.590T>G p.M197R | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV63738983; called by muse, mutect2, varscan2
- APC | c.7525C>T p.P2509S | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); catalogued as rs1473460192, COSV57343647; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP44 | c.1424C>A p.P475Q | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52393884; called by muse, mutect2, varscan2
- ATP8B4 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52715231; called by muse, mutect2, varscan2
- ATXN2 | c.1964C>T p.P655L (on ENST00000550104; = p.P495L on NM_002973.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as rs145598979, COSV101112667; called by muse, mutect2, varscan2
- BEND4 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV72469092; called by muse, mutect2, varscan2
- C8B | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.082); catalogued as rs747647469, COSV64776503; called by muse, mutect2, varscan2
- CACNA1B | c.6563G>A p.R2188K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53125694; called by muse, mutect2
- CACNA1E | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62394284; called by muse, mutect2, varscan2
- CACNG5 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50055699, COSV50057188; called by muse, mutect2, varscan2
- CAMTA1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57887236, COSV57906544; called by muse, mutect2, varscan2
- CCBE1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140934817, COSV67949898; called by muse, mutect2, varscan2
- CCDC102B | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV60141499; called by muse, mutect2, varscan2
- CCDC178 | c.1986G>A p.M662I (on ENST00000383096 / NM_001105528.3; = p.M624I on NM_198995.3) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs867565267, COSV55759521; called by muse, mutect2
- CD1C | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs752096647, COSV63806415, COSV63806907; called by muse, mutect2, varscan2
- CDH6 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54065315; called by muse, mutect2, varscan2
- CEP89 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768932479, COSV59864189; called by muse, mutect2, varscan2
- CHAT | c.1083G>A p.W361* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs753310881, COSV60322151; called by muse, mutect2
- CKAP5 | c.4558C>T p.P1520S | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100370788; called by muse, mutect2, varscan2
- CLVS2 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs750382549, COSV51562393, COSV51567732; called by muse, mutect2, varscan2
- CMYA5 | c.12194C>T p.S4065F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.039); catalogued as COSV69745538; called by muse, mutect2, varscan2
- CNTN6 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV63168511, COSV63171822; called by muse, mutect2, varscan2
- COL12A1 | c.2615G>A p.G872E | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV59395823; called by muse, varscan2
- COL3A1 | c.3568C>T p.P1190S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV58581994; called by muse, mutect2
- COL9A1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV57881850; called by muse, mutect2, varscan2
- COLEC11 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52593692; called by muse, mutect2, varscan2
- CSMD3 | c.7733G>A p.G2578E (on ENST00000297405 / NM_001363185.1; = p.G2474E on NM_052900.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52177476; called by muse, mutect2, varscan2
- CYP2C19 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.11); catalogued as rs867067400, COSV64907708; called by muse, mutect2, varscan2
- DACH1 | c.1957G>A p.D653N (on ENST00000619232 / NM_001366712.1; = p.D399N on NM_004392.6) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as COSV57488700; called by muse, mutect2, varscan2
- DCAF4 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV62319556; called by muse, mutect2, varscan2
- DLK2 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.812); catalogued as COSV55086104, COSV55087645; called by muse, mutect2, varscan2
- DMBT1 | c.5816A>T p.N1939I (on ENST00000338354 / NM_001377530.1; = p.N1182I on NM_004406.3) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.675); catalogued as COSV57543711; called by muse, mutect2, varscan2
- DNAH10 | c.1000-1G>A p.X334_splice (on ENST00000409039; = p.X273_splice on NM_207437.3) | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as rs200903075, COSV68993612; called by muse, mutect2, varscan2
- DNAH14 | c.571C>T p.Q191* (on ENST00000445597; = p.Q14* on NM_144989.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV64781018; called by muse, mutect2, varscan2
- DNAH8 | c.9090-1G>A p.X3030_splice | Splice Site (SNP) | VAF 29/94 reads (31%) | catalogued as COSV100546717, COSV59444366; called by muse, mutect2, varscan2
- DYM | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs758432311, COSV53983159; called by muse, mutect2, varscan2
- EHHADH | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs776874092, COSV51628497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF5A2 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs865793416, COSV55543343; called by muse, varscan2
- ELMO1 | c.41G>A p.W14* | Nonsense Mutation (SNP) | VAF 67/205 reads (33%) | catalogued as COSV60304255; called by muse, mutect2, varscan2
- EXOC2 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV100033642; called by muse, mutect2, varscan2
- FCAR | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV62029618; called by mutect2, varscan2
- FCRL5 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1181237308, COSV62514429, COSV99052689; called by muse, mutect2, varscan2
- FXYD4 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs150156235, COSV72052652; called by muse, mutect2, varscan2
- GAD1 | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60152324; called by muse, mutect2, varscan2
- GPATCH8 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV59193394; called by muse, mutect2, varscan2
- GREB1 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52186859; called by muse, mutect2, varscan2
- GRIK5 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as rs1568934197, COSV53478530; called by muse, mutect2, varscan2
- HELZ | c.3947G>A p.R1316K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.931); catalogued as rs201494578, COSV62378446; called by muse, mutect2, varscan2
- HOXB1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV53317214; called by muse, mutect2, varscan2
- IFT122 | c.1658C>T p.P553L (on ENST00000348417 / NM_052989.3; = p.P494L on NM_018262.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV56202979; called by muse, mutect2, varscan2
- IGFBP6 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV56857336; called by muse, mutect2, varscan2
- IL27RA | c.335A>G p.Q112R | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54600717; called by muse, mutect2, varscan2
- INSRR | c.1741A>G p.T581A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.098); catalogued as COSV63873021; called by muse, mutect2, varscan2
- JAM2 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs752362595, COSV57256512; called by muse, mutect2
- KCNB1 | c.1232T>A p.I411N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65568208; called by muse, mutect2, varscan2
- KDM5A | c.4259C>T p.P1420L | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV66992304, COSV66995054; called by muse, mutect2, varscan2
- KMO | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1042396037, COSV59363386; called by muse, mutect2, varscan2
- LILRA1 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as COSV52180683, COSV52182832; called by muse, mutect2
- LPAR4 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 56/90 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606517, COSV70912599; called by muse, mutect2, varscan2
- LRIT3 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as COSV100016125; called by muse, mutect2, varscan2
- LRP2 | c.3323C>T p.S1108F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV55552711; called by muse, mutect2, varscan2
- LRRFIP2 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772292695, COSV60867597; called by muse, mutect2, varscan2
- LYST | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67706933; called by muse, mutect2, varscan2
- MAB21L1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs866884698, COSV59783031; called by muse, mutect2, varscan2
- MAGEC1 | c.2725G>A p.D909N | Missense Mutation (SNP) | VAF 117/176 reads (66%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV53572643; called by muse, mutect2, varscan2
- MECOM | c.923C>T p.P308L (on ENST00000468789 / NM_001105078.4; = p.P496L on NM_004991.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52962727, COSV99245010; called by muse, mutect2, varscan2
- MPP6 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56038113; called by muse, mutect2, varscan2
- MUC16 | c.6265G>A p.E2089K | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV67465145; called by muse, mutect2, varscan2
- MYBPC3 | c.1073A>C p.D358A | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV57027084; called by muse, mutect2, varscan2
- MYH2 | c.744T>A p.G248= | Splice Region (SNP) | VAF 26/119 reads (22%) | catalogued as COSV55438077; called by muse, mutect2, varscan2
- NAP1L2 | c.725A>C p.D242A | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV65172501; called by muse, mutect2, varscan2
- NCKAP1L | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as COSV53206664; called by muse, mutect2
- NLRC4 | c.1785A>T p.L595F | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as COSV61592596; called by muse, mutect2, varscan2
- NLRP9 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60466418; called by muse, mutect2
- NTNG1 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53970931; called by muse, mutect2, varscan2
- OGG1 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as rs1287943350, COSV56538731; called by muse, mutect2, varscan2
- OR10G3 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57809988, COSV57810245; called by muse, mutect2, varscan2
- OR11H4 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.247); catalogued as COSV100197520; called by muse, mutect2, varscan2
- OR1J2 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58944364; called by muse, mutect2, varscan2
- OR3A1 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV60163052; called by muse, mutect2, varscan2
- OR4E2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57731738; called by muse, mutect2, varscan2
- OR4K5 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60003491; called by muse, mutect2, varscan2
- OR5D13 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV62333673, COSV62335009; called by muse, mutect2, varscan2
- OR5H15 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV62947970; called by muse, varscan2
- OR6V1 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs776161537, COSV69237110, COSV69237234; called by muse, mutect2, varscan2
- OTUD6A | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs141916254, COSV57973597; called by muse, mutect2, varscan2
- PARD3B | c.2819C>T p.S940L (on ENST00000406610 / NM_001302769.2; = p.S871L on NM_057177.7) | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV62511055; called by muse, mutect2, varscan2
- PCDHA1 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs1554118172, COSV65372505; called by muse, mutect2, varscan2
- PCDHB7 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs147934905, COSV50767440; called by muse, mutect2, varscan2
- PCDHGA4 | c.1704T>G p.S568R | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.678); catalogued as COSV53945801; called by muse, varscan2
- PCDHGA9 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as rs774624797, COSV53945821; called by muse, mutect2, varscan2
- PDP2 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV61240565; called by muse, mutect2, varscan2
- PLXNA4 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV58124935; called by muse, mutect2, varscan2
- POSTN | c.2349G>A p.E783= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65712945; called by muse, mutect2
- PRELID1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV57463304; called by muse, mutect2, varscan2
- PRRG3 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 57/82 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64851031; called by muse, mutect2
- PRUNE2 | c.8081C>T p.P2694L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1397329110, COSV65041435, COSV65043322; called by muse, mutect2, varscan2
- PYGM | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV51216763, COSV99376808; called by muse, mutect2, varscan2
- RELN | c.7585C>T p.Q2529* | Nonsense Mutation (SNP) | VAF 36/65 reads (55%) | catalogued as COSV59001493; called by muse, mutect2, varscan2
- RNF113B | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57435035; called by muse, mutect2, varscan2
- RNF31 | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV100141928, COSV60726796; called by muse, varscan2
- ROS1 | c.6395G>A p.S2132N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV63855082; called by muse, mutect2, varscan2
- RPL27 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as rs781041828, COSV53814775; called by muse, mutect2, varscan2
- SCNN1G | c.559A>C p.I187L | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as COSV55598840; called by muse, mutect2, varscan2
- SLC30A10 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV104415222, COSV63071457; called by muse, mutect2, varscan2
- SLC30A8 | c.165T>G p.S55R | Missense Mutation (SNP) | VAF 195/492 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV69970511; called by muse, varscan2
- SLC5A5 | c.423G>A p.T141= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV55832976, COSV55833461; called by muse, mutect2, varscan2
- SNTG1 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.97); catalogued as rs1450704094, COSV52442716; called by muse, mutect2, varscan2
- SPATA16 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV63529177, COSV63531150; called by muse, mutect2, varscan2
- SPIDR | c.2533T>C p.C845R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV52377008; called by mutect2, varscan2
- SRCAP | c.4604C>T p.P1535L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV52672467; called by muse, mutect2
- ST6GAL2 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | PolyPhen probably damaging (0.999); catalogued as COSV62416601; called by muse, mutect2
- STC2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV54179761; called by muse, mutect2, varscan2
- TAF7L | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as COSV63300000; called by muse, mutect2, varscan2
- TBXAS1 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1199815983, COSV54945089; called by muse, mutect2
- TLL1 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV50278891; called by muse, mutect2, varscan2
- TMC5 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs369805960; called by muse, mutect2, varscan2
- TMPRSS15 | c.2389C>T p.P797S | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53039653; called by muse, mutect2, varscan2
- TNR | c.1636G>A p.G546R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.974); catalogued as COSV54885161; called by muse, mutect2, varscan2
- TPSG1 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52354506; called by muse, mutect2, varscan2
- TPSG1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772861611, COSV52354516; called by muse, mutect2, varscan2
- TTN | c.68807C>T p.S22936F (on ENST00000591111; = p.S15512F on NM_003319.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | PolyPhen possibly damaging (0.664); catalogued as COSV59998498; called by muse, mutect2, varscan2
- TTN | c.17761G>A p.E5921K (on ENST00000591111; = p.E4994K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | PolyPhen possibly damaging (0.819); catalogued as COSV59996401; called by muse, mutect2, varscan2
- ZBED9 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.987); catalogued as COSV71729397; called by muse, mutect2, varscan2
- ZFR | c.3118C>G p.Q1040E | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV54053003; called by muse, varscan2
- ZNF207 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV58299840; called by muse, mutect2, varscan2
- ZNF516 | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV71587005; called by muse, mutect2, varscan2
- ASAH2 | c.1318A>T p.N440Y | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRMPD1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.236); called by muse, mutect2
- HNF1B | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 102/472 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IGHG4 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMEL | c.251_253del p.F84del | In Frame Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel, varscan2
- PRAMEF17 | c.593T>C p.L198S | Missense Mutation (SNP) | VAF 10/322 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.102); called by muse, mutect2
- ACE | c.996C>T p.S332= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs767127845, COSV52006685; called by muse, mutect2, varscan2
- ACSL5 | c.669G>A p.G223= (on ENST00000354273; = p.G279= on NM_016234.3) | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs748431697, COSV61130558; called by muse, mutect2, varscan2
- ADGRG4 | c.5070C>T p.S1690= | Silent (SNP) | VAF 59/100 reads (59%) | catalogued as rs1231479923, COSV54955783; called by muse, mutect2, varscan2
- ADGRL4 | c.1161G>A p.E387= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV66061594; called by muse, mutect2, varscan2
- ADGRV1 | c.1293G>A p.A431= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs773901506, COSV67977462; called by muse, mutect2, varscan2
- ADGRV1 | c.12582C>T p.F4194= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV67984984; called by muse, mutect2, varscan2
- AGO2 | c.2490C>T p.T830= | Silent (SNP) | VAF 36/268 reads (13%) | catalogued as COSV55047447; called by muse, mutect2, varscan2
- APOBEC1 | c.126C>T p.I42= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV57548923; called by muse, mutect2, varscan2
- ARHGAP28 | c.696G>A p.G232= (on ENST00000383472 / NM_001366230.1; = p.G73= on NM_001010000.3) | Silent (SNP) | VAF 29/159 reads (18%) | catalogued as COSV51630979, COSV51637108; called by muse, mutect2, varscan2
- ARSF | c.618G>A p.G206= | Silent (SNP) | VAF 34/48 reads (71%) | catalogued as rs777293098, COSV63839587; called by muse, mutect2, varscan2
- ATP8A2 | c.2715G>A p.Q905= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV54951328; called by muse, mutect2, varscan2
- BFSP2 | c.688C>T p.L230= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV56588815; called by muse, mutect2, varscan2
- BMP3 | c.547C>T p.L183= | Silent (SNP) | VAF 41/183 reads (22%) | catalogued as rs147415195; called by muse, mutect2, varscan2
- CCDC180 | c.3597C>T p.S1199= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1240231119, COSV100826716; called by muse, mutect2, varscan2
- CCDC73 | c.2772G>A p.S924= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs763207450, COSV58798432; called by muse, mutect2, varscan2
- CCL4L2 | c.102C>T p.C34= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- CEACAM18 | c.918C>T p.I306= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV67282839; called by muse, mutect2, varscan2
- CLSTN3 | c.795C>T p.F265= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV56936211; called by muse, mutect2, varscan2
- COL15A1 | c.267G>A p.R89= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV66644594; called by muse, mutect2, varscan2
- COL4A5 | c.1818G>A p.G606= | Silent (SNP) | VAF 56/79 reads (71%) | catalogued as COSV60361378; called by muse, mutect2, varscan2
- CYP2A13 | c.789C>T p.S263= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs1341782955, COSV57837368; called by muse, mutect2, varscan2
- DSCAML1 | c.5955C>T p.P1985= (on ENST00000321322; = p.P1925= on NM_020693.4) | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV58390375; called by muse, mutect2, varscan2
- DSP | c.2568C>T p.F856= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as rs746036365, COSV65792648; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUOX1 | c.9C>T p.F3= | Silent (SNP) | VAF 44/166 reads (27%) | catalogued as COSV50993555; called by muse, mutect2, varscan2
- FRMPD3 | c.201C>T p.F67= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as rs372670453, COSV99345357; called by muse, mutect2, varscan2
- GRM4 | c.1851C>T p.I617= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs781063155, COSV65212883; called by muse, mutect2, varscan2
- GUCY1A2 | c.1047G>A p.Q349= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV56486320; called by muse, mutect2, varscan2
- GUCY2C | c.1575C>T p.F525= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV53790121, COSV99663870; called by muse, varscan2
- HHIP | c.477C>T p.F159= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as COSV56845143; called by muse, mutect2, varscan2
- HSD3B7 | c.891C>T p.F297= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as COSV52680513; called by muse, mutect2
- IGHV1OR15-9 | c.177C>T p.A59= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- IGLV2-23 | c.201C>T p.L67= | Silent (SNP) | VAF 26/145 reads (18%) | catalogued as rs771843627; called by muse, mutect2, varscan2
- ITGB8 | c.2010C>T p.V670= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs370772138; called by muse, mutect2, varscan2
- KIAA1614 | c.876C>T p.S292= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV62552823; called by muse, mutect2, varscan2
- KRT75 | c.597C>T p.L199= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV52872707; called by muse, varscan2
- LPA | c.3021C>T p.V1007= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV60301692; called by muse, mutect2, varscan2
- MLF1 | c.552C>T p.F184= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV63033535; called by muse, mutect2, varscan2
- MSX2 | c.483C>T p.F161= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV53327045; called by muse, varscan2
- MYOF | c.1638G>A p.E546= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV63704081; called by muse, mutect2, varscan2
- OPRK1 | c.882C>T p.I294= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV55570408; called by muse, mutect2, varscan2
- OR1D2 | c.139C>T p.L47= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as COSV58921584; called by muse, mutect2, varscan2
- OR1F1 | c.792C>T p.S264= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs770492320, COSV58961008; called by muse, mutect2, varscan2
- OR2G6 | c.717G>A p.G239= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs779028414, COSV58574160; called by muse, mutect2, varscan2
- OR4K2 | c.897G>A p.R299= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1291478184, COSV53848607, COSV53849458; called by muse, mutect2, varscan2
- OR51Q1 | c.730C>T p.L244= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV56178860; called by muse, mutect2, varscan2
- OR5P2 | c.87C>T p.I29= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV61489901; called by muse, mutect2, varscan2
- PARP8 | c.1419T>C p.S473= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99891470; called by muse, mutect2, varscan2
- PCDHA13 | c.2184C>T p.T728= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV56500415, COSV99169458; called by muse, mutect2, varscan2
- PFAS | c.843C>T p.V281= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV58980213, COSV58983495; called by muse, mutect2, varscan2
- PSEN1 | c.261C>T p.V87= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs774257366, COSV56194448; called by muse, mutect2, varscan2
- PSMD3 | c.399C>T p.P133= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV52857524; called by muse, mutect2, varscan2
- RAPGEF4 | c.1347C>T p.D449= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV51388675; called by muse, mutect2, varscan2
- SCN5A | c.1434G>A p.R478= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as rs200583438, COSV61123837; called by muse, mutect2, varscan2
- SERPINA11 | c.297C>T p.I99= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs764191151, COSV100594004, COSV58241845; called by muse, mutect2, varscan2
- SERPINB12 | c.423G>A p.T141= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs771263213, COSV54033119; called by muse, mutect2, varscan2
- SIN3A | c.2658C>T p.F886= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV64582901, COSV64584497; called by muse, mutect2, varscan2
- STAB1 | c.4188G>A p.G1396= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV58736036; called by muse, mutect2, varscan2
- STAB2 | c.1302G>A p.V434= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV66338799, COSV66341521; called by muse, mutect2, varscan2
- SYN3 | c.540G>A p.L180= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV60508106; called by muse, mutect2, varscan2
- TEP1 | c.3714C>T p.S1238= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV52992380; called by muse, mutect2
- THBS2 | c.3450G>A p.L1150= | Silent (SNP) | VAF 35/107 reads (33%) | catalogued as rs1172095608, COSV64678800; called by muse, mutect2, varscan2
- THG1L | c.39G>A p.L13= | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as COSV51452831; called by muse, mutect2, varscan2
- TMEM119 | c.249C>T p.F83= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs750202677, COSV67188719; called by muse, mutect2, varscan2
- TTN | c.41292C>T p.F13764= (on ENST00000591111; = p.F6340= on NM_003319.4) | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs779560487, COSV59950093; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.26922C>T p.F8974= (on ENST00000591111; = p.F8047= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV59874672; called by muse, mutect2, varscan2
- ZNF112 | c.297C>T p.S99= (on ENST00000337401 / NM_001083335.2; = p.S93= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as rs1188574038, COSV61619989; called by muse, mutect2
- CPLANE1 | c.*2794C>T | 3'UTR (SNP) | VAF 8/52 reads (15%) | catalogued as COSV57057027; called by muse, mutect2, varscan2
- MIR299 | n.46G>A | RNA (SNP) | VAF 14/62 reads (23%) | catalogued as rs954825951; called by muse, mutect2, varscan2
- SF1 | c.*309C>T | 3'UTR (SNP) | VAF 28/112 reads (25%) | catalogued as COSV99918321; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2282C>T | Intron (SNP) | VAF 10/40 reads (25%) | catalogued as COSV54096366; called by muse, mutect2, varscan2
- SNORD115-7 | n.52C>T | RNA (SNP) | VAF 28/175 reads (16%) | catalogued as rs767472659; called by muse, mutect2, varscan2
- UBTFL2 | n.883T>A | RNA (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
